Somatic mutation profile of tumor specimen 0DQKYN from CCDI case PBCFFC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.7 years (978 days).
Specimen 0DQKYN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ebe86341-a462-4440-8376-e372af86ff25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQKZJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c86daef1-3a3b-48f9-a9e5-a5a0cb4440fc

The open-access MAF lists 3 somatic variants for this specimen: 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KPRP | c.1389C>T p.C463= | Silent (SNP) | VAF 56/375 reads (15%) | called by muse, mutect2, varscan2
- LTBP4 | c.2011+101_2011+132del | Intron (DEL) | VAF 16/43 reads (37%) | called by mutect2, pindel
- TTN | c.10303+2513G>A | Intron (SNP) | VAF 332/677 reads (49%) | catalogued as rs748260785, COSV104415652; called by muse, mutect2, varscan2
